Somatic mutation profile of tumor specimen TCGA-50-5072-01A (aliquot TCGA-50-5072-01A-21D-1855-08) from TCGA case TCGA-50-5072, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 74.0 years (27,036 days).
Specimen TCGA-50-5072-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dcc71d2d-9707-4234-a3e7-49b9cf977250.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-5072-10A (Blood Derived Normal), aliquot TCGA-50-5072-10A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/009254a2-ea81-4c76-8044-7267a9f81364

The open-access MAF lists 175 somatic variants for this specimen: 136 protein-altering or splice-affecting, 39 silent.
By variant classification: Missense Mutation 111, Silent 39, Nonsense Mutation 10, Frame Shift Del 6, Splice Site 5, Frame Shift Ins 2, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAR2 | c.1123G>T p.V375L | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100299103; called by muse, mutect2, varscan2
- ADGRF2 | c.526A>G p.T176A (on ENST00000296862 / NM_001368115.2; = p.T108A on NM_153839.7) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV57291369; called by muse, mutect2, varscan2
- ADGRL4 | c.397-1G>C p.X133_splice | Splice Site (SNP) | VAF 7/22 reads (32%) | catalogued as COSV66064893; called by muse, mutect2, varscan2
- AHNAK | c.14020G>T p.V4674L | Missense Mutation (SNP) | VAF 84/495 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.942); catalogued as COSV57226634; called by muse, mutect2, varscan2
- ANPEP | c.1162C>T p.H388Y | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55594180; called by muse, mutect2, varscan2
- ARMC5 | c.1826G>A p.R609H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs767369427, COSV51659395; called by muse, mutect2, varscan2
- ARRDC5 | c.789C>A p.N263K (on ENST00000381781; = p.N249K on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.131); catalogued as COSV67788236; called by muse, mutect2, varscan2
- ATRIP | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 82/224 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV100202788, COSV57176504, COSV57178612; called by muse, mutect2, varscan2
- ATXN2 | c.1859C>T p.P620L (on ENST00000550104; = p.P460L on NM_002973.4) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs780736733, COSV66485640; called by muse, mutect2, varscan2
- CAGE1 | c.2230A>T p.R744* (on ENST00000512086; = p.R608* on NM_205864.3) | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV57080999; called by muse, mutect2
- CASP1 | c.627G>T p.S209= (on ENST00000436863 / NM_033292.4; = p.S188= on NM_001223.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 17/103 reads (17%) | catalogued as COSV62057361; called by muse, mutect2, varscan2
- CCDC102B | c.350G>T p.R117M | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV60152123; called by muse, mutect2, varscan2
- CCDC57 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as rs541959209, COSV66435514; called by muse, mutect2, varscan2
- CCKBR | c.457T>A p.Y153N | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58104642; called by muse, mutect2, varscan2
- CD5L | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 44/125 reads (35%) | catalogued as COSV63821147, COSV63822911; called by muse, mutect2, varscan2
- CDKN1B | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 61/155 reads (39%) | catalogued as COSV99963743; called by muse, mutect2, varscan2
- CFH | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.06); catalogued as COSV62777477; called by muse, mutect2, varscan2
- CHD8 | c.2388G>A p.W796* (on ENST00000646647 / NM_001170629.2; = p.W517* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | catalogued as rs1555315745, COSV67872346; called by muse, mutect2
- CLCN1 | c.686T>C p.V229A | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV58373746; called by muse, mutect2, varscan2
- COL11A1 | c.2866T>A p.F956I | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV62194473; called by muse, mutect2, varscan2
- COL12A1 | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV59405552; called by muse, mutect2, varscan2
- CPSF6 | c.770A>G p.Q257R | Missense Mutation (SNP) | VAF 63/129 reads (49%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.775); catalogued as COSV57018062; called by muse, mutect2, varscan2
- CRB1 | c.3363G>T p.Q1121H | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100957588, COSV66329656; called by muse, mutect2, varscan2
- CRB1 | c.3364G>T p.E1122* | Nonsense Mutation (SNP) | VAF 23/92 reads (25%) | catalogued as COSV100957590, COSV66328587; called by muse, mutect2, varscan2
- CYP19A1 | c.1484G>A p.R495K | Missense Mutation (SNP) | VAF 45/183 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV53061921; called by muse, mutect2, varscan2
- DLGAP1 | c.2576C>G p.P859R | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59829998; called by muse, mutect2, varscan2
- DNAH3 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.153); catalogued as COSV54545487; called by muse, mutect2, varscan2
- DNAJC5G | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56080601; called by muse, mutect2, varscan2
- DOT1L | c.493+1G>T p.X165_splice | Splice Site (SNP) | VAF 17/54 reads (31%) | catalogued as COSV67112757; called by muse, mutect2, varscan2
- DSEL | c.850G>T p.D284Y | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV59494060; called by muse, mutect2, varscan2
- DUSP16 | c.1703C>T p.S568F | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV53809468; called by muse, mutect2, varscan2
- DYRK3 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT tolerated (0.79); PolyPhen benign (0.028); catalogued as COSV65607586; called by muse, mutect2, varscan2
- EIF2D | c.1223G>A p.G408D | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.122); catalogued as COSV55115227; called by muse, mutect2, varscan2
- EPHB1 | c.996C>G p.I332M | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.93); catalogued as COSV67661039, COSV67669294; called by muse, mutect2, varscan2
- ERO1A | c.589T>A p.W197R | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.102); catalogued as COSV101193553; called by muse, mutect2, varscan2
- F11 | c.127G>T p.A43S | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM105317, COSV53009200; called by muse, mutect2, varscan2
- F13A1 | c.1904T>A p.I635N | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53565735; called by muse, mutect2, varscan2
- FIGNL1 | c.1145A>G p.K382R | Missense Mutation (SNP) | VAF 73/277 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV63553992; called by muse, mutect2, varscan2
- FN1 | c.2149C>A p.P717T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs1022716034, COSV60561785; called by muse, mutect2, varscan2
- FOXD4L5 | c.400A>G p.I134V | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV101072971; called by mutect2, varscan2
- FSCB | c.940G>T p.V314F | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.578); catalogued as COSV61219337; called by muse, mutect2, varscan2
- GPI | c.448A>G p.T150A | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.288); catalogued as COSV62894749; called by muse, mutect2, varscan2
- GRIN2D | c.1795G>T p.V599F | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.988); catalogued as COSV54381777; called by muse, mutect2, varscan2
- GTPBP1 | c.1348A>T p.M450L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.075); catalogued as COSV99322797; called by muse, mutect2, varscan2
- H2AC20 | c.362C>T p.T121I | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.181); catalogued as rs782388939, COSV58612190, COSV58612981; called by muse, mutect2, varscan2
- HACD1 | c.710G>T p.R237I | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.18); catalogued as COSV63517057; called by muse, mutect2, varscan2
- HCLS1 | c.1190A>C p.Y397S | Missense Mutation (SNP) | VAF 67/284 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV57526915; called by muse, mutect2, varscan2
- HLX | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV65045530; called by muse, mutect2, varscan2
- IGHE | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs781819607; called by muse, mutect2, varscan2
- JAKMIP2 | c.2283G>T p.K761N | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV54613890; called by muse, mutect2, varscan2
- KIAA1755 | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 88/284 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV54076543; called by muse, mutect2, varscan2
- KNOP1 | c.446A>G p.K149R | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.593); catalogued as COSV99574990; called by muse, mutect2, varscan2
- KRTAP5-8 | c.552G>T p.Q184H | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV101273107; called by muse, mutect2, varscan2
- LRATD2 | c.104C>A p.S35Y | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100513495; called by muse, mutect2, varscan2
- LRRN4 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as COSV66645299; called by muse, mutect2, varscan2
- LRRTM1 | c.1262A>G p.N421S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.025); catalogued as COSV54445771; called by muse, mutect2, varscan2
- LTF | c.1170C>A p.C390* | Nonsense Mutation (SNP) | VAF 16/42 reads (38%) | catalogued as COSV51611416; called by muse, mutect2, varscan2
- MAGI2 | c.3130C>A p.P1044T | Missense Mutation (SNP) | VAF 131/438 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.399); catalogued as COSV62631841; called by muse, mutect2, varscan2
- MAML3 | c.3229C>T p.P1077S | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as rs1485080618, COSV72209972; called by muse, mutect2, varscan2
- MAST3 | c.805G>C p.V269L | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV53225726; called by muse, mutect2
- MAT2A | c.443A>T p.E148V | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52090080; called by muse, mutect2, varscan2
- MGAM | c.1093G>T p.E365* | Nonsense Mutation (SNP) | VAF 54/133 reads (41%) | catalogued as COSV72075456; called by muse, mutect2, varscan2
- MLC1 | c.1009G>A p.G337S | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.107); catalogued as COSV61118573; called by muse, mutect2, varscan2
- MRC2 | c.2710G>T p.D904Y | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57643671; called by muse, mutect2, varscan2
- MUC5B | c.8884C>A p.R2962S | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV101499923; called by muse, mutect2, varscan2
- NARS1 | c.1427C>T p.S476L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56878003; called by muse, mutect2, varscan2
- NF1 | c.2375T>A p.L792H | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.842); catalogued as COSV62217405; called by muse, mutect2, varscan2
- NPAP1 | c.217C>A p.P73T | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.322); catalogued as COSV100274494; called by muse, mutect2, varscan2
- NPAP1 | c.218C>A p.P73H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV100274495; called by muse, mutect2, varscan2
- NPAP1 | c.3215G>A p.G1072E | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.065); catalogued as rs755028786, COSV100275979, COSV61508902; called by muse, mutect2, varscan2
- NPC1 | c.2692G>T p.D898Y | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as CM1413846, COSV52582837; called by muse, mutect2, varscan2
- NPL | c.709A>G p.K237E | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as COSV51127071; called by muse, mutect2
- OR13C8 | c.868A>G p.M290V | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs761064703, COSV58612209; called by muse, mutect2, varscan2
- OR2M7 | c.289T>A p.C97S | Missense Mutation (SNP) | VAF 175/454 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58740405; called by muse, mutect2, varscan2
- OR51A2 | c.469C>G p.L157V | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.437); catalogued as COSV100984980; called by muse, mutect2, varscan2
- OR51S1 | c.838C>A p.H280N | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as COSV59059819; called by muse, mutect2, varscan2
- OR5AR1 | c.373G>T p.A125S | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV57255063; called by muse, mutect2, varscan2
- OR5J2 | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV56622824; called by muse, mutect2, varscan2
- OR8H2 | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100542082; called by muse, mutect2
- OTUD4 | c.674C>G p.P225R (on ENST00000447906 / NM_001366057.1; = p.P160R on NM_001102653.1) | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.219); catalogued as COSV56851488; called by muse, mutect2, varscan2
- OXCT1 | c.322A>T p.I108L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.063); catalogued as COSV52176061; called by muse, mutect2
- PCDHB11 | c.518G>T p.S173I | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.499); catalogued as COSV53382886; called by muse, mutect2, varscan2
- PCDHB6 | c.1840G>A p.G614S | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV50719876; called by muse, mutect2
- PRKCB | c.260C>A p.P87H | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57786666, COSV57796821; called by muse, mutect2, varscan2
- PRSS1 | c.137A>T p.H46L | Missense Mutation (SNP) | VAF 59/166 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV61196615; called by muse, varscan2
- PTPRF | c.2399A>C p.Y800S | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV63448220; called by muse, mutect2, varscan2
- RAB15 | c.414+1G>T p.X138_splice (on ENST00000533601 / NM_001308154.2; = p.X182_splice on NM_198686.3) | Splice Site (SNP) | VAF 65/302 reads (22%) | catalogued as COSV50825317; called by muse, mutect2, varscan2
- REV3L | c.5027A>T p.K1676M | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62622417; called by muse, mutect2, varscan2
- RFPL2 | c.895G>A p.V299I | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as rs778808289, COSV99963904; called by mutect2, varscan2
- RPS6KC1 | c.3168dup p.T1057Yfs*22 | Frame Shift Ins (INS) | VAF 14/136 reads (10%) | catalogued as rs775247030; called by mutect2, pindel
- RTN1 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.041); catalogued as COSV50725338; called by muse, mutect2
- RTP2 | c.296G>T p.C99F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64079379; called by muse, mutect2, varscan2
- RXRG | c.206C>A p.P69Q | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV63232989; called by muse, mutect2, varscan2
- RYR3 | c.2675G>T p.G892V | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66805618; called by muse, mutect2, varscan2
- SEPTIN3 | c.1059del p.C354Afs*46 | Frame Shift Del (DEL) | VAF 32/155 reads (21%) | catalogued as COSV52172419; called by mutect2, pindel, varscan2
- SERPINB13 | c.1030G>T p.E344* | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as COSV54030647, COSV99501089; called by muse, mutect2, varscan2
- SI | c.2933G>C p.R978T | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV52296910; called by muse, mutect2, varscan2
- SLC17A6 | c.459G>T p.R153S | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV54140302; called by muse, mutect2
- SLC19A3 | c.25A>C p.S9R | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV51454508; called by muse, mutect2, varscan2
- SLC24A1 | c.1633C>T p.L545F | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs770378419, COSV56053674; called by muse, mutect2, varscan2
- SLC39A12 | c.1361G>T p.G454V | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760505280, COSV66201849; called by muse, mutect2, varscan2
- SLC39A6 | c.1554G>T p.M518I | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.285); catalogued as COSV52370981; called by muse, mutect2, varscan2
- SMARCA4 | c.3125T>C p.L1042P | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60806363; called by muse, mutect2, varscan2
- SNX4 | c.653+1G>C p.X218_splice | Splice Site (SNP) | VAF 15/63 reads (24%) | catalogued as COSV52540016; called by muse, mutect2, varscan2
- SOX5 | c.2044G>A p.A682T | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs528695217, COSV58628801; called by muse, mutect2, varscan2
- SQSTM1 | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV62435435; called by muse, mutect2, varscan2
- ST18 | c.2590C>T p.Q864* | Nonsense Mutation (SNP) | VAF 25/90 reads (28%) | catalogued as COSV52490091, COSV52506422; called by muse, mutect2, varscan2
- STX3 | c.404A>G p.N135S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs747357728, COSV55700580; called by muse, mutect2, varscan2
- SYNE1 | c.18169A>T p.I6057F (on ENST00000367255 / NM_182961.4; = p.I5986F on NM_033071.3) | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55077423; called by muse, mutect2, varscan2
- TCHH | c.5784C>G p.S1928R | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV64277284; called by muse, mutect2
- TENM3 | c.172C>A p.L58I | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.303); catalogued as COSV69316927; called by muse, mutect2, varscan2
- TMPRSS11E | c.775G>T p.G259C | Missense Mutation (SNP) | VAF 43/296 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV59518693; called by muse, mutect2, varscan2
- TPO | c.2095A>G p.T699A | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV61109410; called by muse, mutect2, varscan2
- TRIM2 | c.1363G>T p.A455S (on ENST00000437508; = p.A482S on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs777739975, COSV104408254, COSV58635498; called by muse, mutect2, varscan2
- TTC21A | c.1342G>C p.E448Q | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.093); catalogued as COSV57188889; called by muse, mutect2
- TTN | c.71959G>C p.D23987H (on ENST00000591111; = p.D16563H on NM_003319.4) | Missense Mutation (SNP) | VAF 122/392 reads (31%) | PolyPhen probably damaging (0.999); catalogued as COSV60288597; called by muse, mutect2, varscan2
- TTN | c.26309G>T p.G8770V (on ENST00000591111; = p.G7843V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/102 reads (14%) | PolyPhen probably damaging (0.99); catalogued as COSV100611949, COSV60288626; called by muse, mutect2, varscan2
- USP1 | c.875C>G p.S292* | Nonsense Mutation (SNP) | VAF 23/80 reads (29%) | catalogued as COSV60575286; called by muse, mutect2, varscan2
- VN1R2 | c.1169A>G p.H390R | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV100447698; called by muse, mutect2, varscan2
- WAPL | c.2315T>C p.I772T | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750612471, COSV53936131; called by muse, mutect2, varscan2
- YLPM1 | c.5492G>A p.R1831K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV53119057; called by muse, mutect2, varscan2
- ZC3H4 | c.1330+2T>A p.X444_splice | Splice Site (SNP) | VAF 36/116 reads (31%) | catalogued as COSV53416433; called by muse, mutect2, varscan2
- ZCCHC14 | c.791A>T p.H264L (on ENST00000268616; = p.H401L on NM_015144.3) | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.422); catalogued as rs775106128, COSV51889725; called by muse, mutect2, varscan2
- ZFP30 | c.1367A>G p.H456R | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63623035; called by muse, mutect2, varscan2
- ZNF18 | c.380G>T p.W127L | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV59552416; called by muse, mutect2, varscan2
- ZNF518B | c.1562A>T p.H521L | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as COSV58724489; called by muse, mutect2, varscan2
- ZNF780A | c.924G>T p.K308N | Missense Mutation (SNP) | VAF 61/239 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.745); catalogued as COSV100574896; called by muse, mutect2, varscan2
- ARID4A | c.1920dup p.Q641Tfs*6 | Frame Shift Ins (INS) | VAF 23/97 reads (24%) | called by mutect2, pindel, varscan2
- CACNA1E | c.4070del p.N1357Tfs*7 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | called by mutect2, pindel, varscan2
- FCGBP | c.2864C>T p.A955V | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (1); PolyPhen probably damaging (0.96); called by muse, mutect2
- FURIN | c.2346_2351del p.E783_R784del | In Frame Del (DEL) | VAF 10/71 reads (14%) | called by mutect2, pindel
- MRC1 | c.3709G>T p.A1237S | Missense Mutation (SNP) | VAF 139/601 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SMOC2 | c.1040del p.L347Qfs*43 (on ENST00000356284 / NM_001166412.2; = p.L358Qfs*43 on NM_022138.3) | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | called by mutect2, pindel, varscan2
- SPDL1 | c.927_928del p.Q310Nfs*2 | Frame Shift Del (DEL) | VAF 20/104 reads (19%) | called by pindel, varscan2
- TDP1 | c.1290_1299del p.G431Lfs*6 | Frame Shift Del (DEL) | VAF 11/90 reads (12%) | called by mutect2, pindel, varscan2
- ZSWIM4 | c.2368del p.Q790Rfs*107 | Frame Shift Del (DEL) | VAF 32/112 reads (29%) | called by mutect2, pindel, varscan2
- AAR2 | c.1122G>T p.V374= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV100299097; called by muse, mutect2, varscan2
- ATP4A | c.279A>G p.P93= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV52871217; called by muse, mutect2, varscan2
- BLNK | c.942A>T p.T314= | Silent (SNP) | VAF 38/134 reads (28%) | catalogued as COSV56414430; called by muse, mutect2, varscan2
- C3orf56 | c.486C>A p.A162= | Silent (SNP) | VAF 46/126 reads (37%) | catalogued as COSV101228912; called by muse, varscan2
- CCPG1 | c.915A>T p.T305= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as COSV60527370; called by muse, mutect2, varscan2
- CNTNAP4 | c.129C>T p.S43= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs1313233255, COSV56696817, COSV56697173; called by muse, mutect2, varscan2
- DNAH7 | c.9540T>C p.N3180= | Silent (SNP) | VAF 20/122 reads (16%) | catalogued as COSV56781283; called by muse, mutect2, varscan2
- F2 | c.1443G>T p.V481= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as COSV61317383; called by muse, mutect2, varscan2
- FHL1 | c.453G>T p.V151= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV61782574; called by muse, mutect2, varscan2
- FZD4 | c.1533G>A p.L511= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as COSV72294655; called by muse, mutect2, varscan2
- GALNT14 | c.1257C>A p.I419= | Silent (SNP) | VAF 31/180 reads (17%) | catalogued as COSV61104014, COSV61110073; called by muse, mutect2, varscan2
- HDGFL1 | c.12C>T p.Y4= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs1017767707, COSV57752895; called by muse, mutect2, varscan2
- IFITM3 | c.357T>A p.I119= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV100068150; called by muse, mutect2
- KIAA0319 | c.153C>T p.T51= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV65501624; called by muse, mutect2, varscan2
- LAMC3 | c.3486C>A p.L1162= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV100735852; called by muse, mutect2, varscan2
- MAGEA12 | c.585C>A p.I195= | Silent (SNP) | VAF 57/151 reads (38%) | catalogued as COSV63295312, COSV63295464; called by muse, mutect2, varscan2
- MC2R | c.708G>A p.V236= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV100562828; called by muse, mutect2, varscan2
- MDN1 | c.2316C>T p.H772= | Silent (SNP) | VAF 24/154 reads (16%) | catalogued as COSV65528749; called by muse, mutect2, varscan2
- MRGPRX4 | c.345C>G p.A115= | Silent (SNP) | VAF 19/148 reads (13%) | catalogued as COSV100049586; called by muse, mutect2, varscan2
- MUC5B | c.8883C>A p.I2961= | Silent (SNP) | VAF 20/161 reads (12%) | catalogued as COSV101499922; called by muse, mutect2, varscan2
- MXRA5 | c.5043C>A p.P1681= | Silent (SNP) | VAF 67/167 reads (40%) | catalogued as rs1361085201, COSV54247243; called by muse, mutect2, varscan2
- MYBPC1 | c.696C>G p.T232= (on ENST00000550270 / NM_206820.2; = p.T257= on NM_002465.4) | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV62256870; called by muse, mutect2
- NEBL | c.2448C>T p.V816= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs764774216, COSV65805291; called by muse, mutect2, varscan2
- NRSN1 | c.585C>T p.T195= | Silent (SNP) | VAF 9/127 reads (7%) | catalogued as COSV101027172; called by muse, mutect2
- OR2AG2 | c.453G>T p.L151= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV58455399, COSV58455984; called by muse, mutect2, varscan2
- OTUD7A | c.684G>T p.V228= | Silent (SNP) | VAF 36/166 reads (22%) | catalogued as COSV61042651; called by muse, mutect2, varscan2
- PCDH15 | c.4881C>A p.S1627= (on ENST00000644397 / NM_001354429.2; = p.S1569= on NM_001142771.2) | Silent (SNP) | VAF 47/203 reads (23%) | catalogued as COSV64692425, COSV64727343; called by muse, mutect2, varscan2
- PCDH15 | c.1575G>A p.G525= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as COSV57309004, COSV57378238; called by muse, mutect2, varscan2
- PCDHB12 | c.1029C>T p.N343= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as rs377624441; called by muse, mutect2, varscan2
- RDH16 | c.594G>T p.G198= | Silent (SNP) | VAF 75/191 reads (39%) | catalogued as COSV62458626; called by muse, mutect2, varscan2
- RSL24D1 | c.66C>T p.V22= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV53066152; called by muse, mutect2, varscan2
- SALL4 | c.114C>A p.P38= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as rs1319172990, COSV53855404; called by muse, mutect2
- SAMSN1 | c.339C>A p.T113= | Silent (SNP) | VAF 40/200 reads (20%) | catalogued as rs1417638535, COSV53476512; called by muse, mutect2, varscan2
- SIN3B | c.318C>T p.L106= | Silent (SNP) | VAF 41/162 reads (25%) | catalogued as rs779213696, COSV56133311; called by muse, mutect2, varscan2
- SMR3A | c.342T>A p.P114= | Silent (SNP) | VAF 39/115 reads (34%) | catalogued as COSV56951200; called by muse, mutect2, varscan2
- SPRR2B | c.90G>T p.P30= | Silent (SNP) | VAF 18/179 reads (10%) | catalogued as COSV100482202, COSV100482274; called by muse, mutect2, varscan2
- STK32C | c.486C>T p.D162= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs377335124; called by mutect2, varscan2
- TAS2R39 | c.219C>A p.G73= | Silent (SNP) | VAF 57/120 reads (48%) | catalogued as COSV71470991; called by muse, mutect2, varscan2
- ZNF382 | c.933C>T p.L311= | Silent (SNP) | VAF 33/129 reads (26%) | catalogued as COSV53091459; called by muse, mutect2, varscan2
